Somatic mutation profile of tumor specimen TCGA-17-Z055-01A (aliquot TCGA-17-Z055-01A-01W-0747-08) from TCGA case TCGA-17-Z055, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z055-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24a099cb-ad1e-4f55-8b31-3e2a46f625ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z055-11A (Solid Tissue Normal), aliquot TCGA-17-Z055-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5f3e48f-49da-4a53-9fb2-d852a262696f

The open-access MAF lists 650 somatic variants for this specimen: 500 protein-altering or splice-affecting, 135 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 429, Silent 135, Nonsense Mutation 37, Splice Site 17, Frame Shift Del 10, Intron 8, Frame Shift Ins 4, Splice Region 3, RNA 3, 5'UTR 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.774A>T p.E258D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52752502, COSV52980614; called by muse, mutect2, varscan2
- ABCA10 | c.3013G>T p.G1005* | Nonsense Mutation (SNP) | VAF 26/418 reads (6%) | catalogued as COSV52220013; called by muse, mutect2
- ACAN | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370865297; called by muse, varscan2
- ADGRA3 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | catalogued as COSV99293443; called by muse, mutect2
- ADGRG1 | c.303A>T p.L101F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV65636190; called by muse, mutect2, varscan2
- ADGRL2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs922086778; called by muse, mutect2
- ADGRL2 | c.1134C>A p.Y378* | Nonsense Mutation (SNP) | VAF 10/263 reads (4%) | catalogued as COSV54678350; called by muse, mutect2
- AGMO | c.512G>T p.W171L | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV61116260; called by muse, mutect2
- AP002512.3 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1298463297, COSV99039480; called by muse, mutect2, varscan2
- ARHGAP5 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.599); catalogued as COSV61534347; called by muse, mutect2
- ARHGEF37 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as COSV61368309; called by muse, mutect2, varscan2
- ARID1A | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100249938, COSV61383854; called by muse, mutect2, varscan2
- ARID2 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV100536221, COSV57604812; called by muse, mutect2, varscan2
- ARSF | c.508G>C p.V170L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755757270, COSV63840558; called by muse, mutect2, varscan2
- ASTN2 | c.1798A>T p.S600C (on ENST00000313400 / NM_001365069.1; = p.S549C on NM_014010.5) | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100530158; called by muse, mutect2, varscan2
- ATP10D | c.3214G>T p.G1072W | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99906339; called by muse, mutect2
- ATRNL1 | c.1742G>T p.R581I | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61808835; called by muse, mutect2, varscan2
- BACH2 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57600976; called by muse, mutect2
- BRINP3 | c.2141C>G p.S714C | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66520834; called by muse, mutect2
- C11orf52 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53715062; called by muse, varscan2
- C1orf21 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99334596; called by muse, mutect2, varscan2
- C4BPA | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891147; called by muse, mutect2
- C9 | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV54675206; called by muse, mutect2, varscan2
- CACNA1E | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759093976, COSV62383640; called by muse, mutect2
- CACNA1I | c.5692C>A p.R1898S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs185177048, COSV60810239; called by muse, mutect2, varscan2
- CAND2 | c.2032G>C p.A678P (on ENST00000456430 / NM_001162499.2; = p.A585P on NM_012298.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV99928971; called by muse, mutect2, varscan2
- CCDC141 | c.2431G>A p.V811I | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs777274990; called by muse, mutect2, varscan2
- CD200R1L | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs773105699; called by muse, mutect2, varscan2
- CDH23 | c.5406G>T p.R1802S | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV56497966; called by muse, mutect2, varscan2
- CENPF | c.8777A>G p.N2926S | Missense Mutation (SNP) | VAF 50/466 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs775447126; called by muse, varscan2
- CHRM2 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57772332; called by muse, mutect2
- CLCA4 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55367296; called by muse, mutect2, varscan2
- CNGB1 | c.3578C>A p.P1193Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV51907040; called by muse, mutect2
- CNKSR2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54257162; called by muse, mutect2
- CNOT6L | c.511C>T p.P171S (on ENST00000504123 / NM_001286790.2; = p.P166S on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53698069; called by muse, mutect2
- CNTNAP5 | c.2272C>A p.P758T | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1293024758; called by muse, mutect2
- COL22A1 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs184984000; called by muse, mutect2, varscan2
- COX8C | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs113042438; called by muse, varscan2
- CR2 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1382161036; called by muse, mutect2
- CTNND2 | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV58931686; called by muse, mutect2
- CUBN | c.2576C>G p.T859S | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.577); catalogued as COSV100912015; called by muse, mutect2
- CYP7A1 | c.255C>A p.Y85* | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | catalogued as COSV56963626; called by muse, mutect2
- DDX23 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as rs770776553, COSV100339977; called by muse, mutect2
- DIAPH3 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1283256298; called by muse, mutect2
- DICER1 | c.3578A>G p.N1193S | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1288723916, COSV58627616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.3250G>T p.E1084* | Nonsense Mutation (SNP) | VAF 39/312 reads (13%) | catalogued as COSV100179507; called by muse, mutect2, varscan2
- EPHA7 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV65179426; called by muse, mutect2
- EXO1 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190558024; called by muse, mutect2
- FAM91A1 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV100593509; called by muse, mutect2, varscan2
- FGB | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); catalogued as COSV57417388, COSV57418309; called by muse, mutect2
- FMO1 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1013504372; called by muse, mutect2
- FRAS1 | c.1145G>T p.C382F | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53628509; called by muse, mutect2
- FSIP2 | c.20621C>A p.S6874Y | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58103499; called by muse, mutect2
- GABRA4 | c.1206C>A p.N402K | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs867684684; called by muse, mutect2
- GOLGA3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs779457963, COSV52633560; called by muse, mutect2, varscan2
- GPR32 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs776291261; called by muse, mutect2, varscan2
- GRIK1 | c.2495T>A p.V832E | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV58721520; called by mutect2, varscan2
- H1-3 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs144176369; called by muse, mutect2, varscan2
- HCK | c.581C>G p.T194S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99394069; called by mutect2, varscan2
- IGSF8 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753924525; called by mutect2, varscan2
- IL5RA | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1559875281; called by muse, mutect2, varscan2
- INHBA | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221739; called by muse, mutect2
- INO80 | c.1892A>T p.Y631F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV62743856; called by mutect2, varscan2
- KANK1 | c.1832A>G p.N611S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs746823315; called by muse, mutect2, varscan2
- KCNA5 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV52904706; called by muse, mutect2, varscan2
- KCNH1 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55080160; called by muse, mutect2
- KCNK1 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64034562; called by muse, mutect2
- KCNK1 | c.750G>A p.T250= | Splice Region (SNP) | VAF 20/247 reads (8%) | catalogued as rs773349901, COSV64036340; called by muse, mutect2
- KCNN3 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV55227513; called by muse, mutect2, varscan2
- KCNT2 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV54106639; called by muse, mutect2, varscan2
- KDM5C | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV64772273; called by muse, mutect2, varscan2
- KIF4B | c.3514A>T p.M1172L | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1378030169; called by muse, mutect2
- KLF10 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); catalogued as rs1267712215; called by muse, mutect2, varscan2
- LGR5 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57002907; called by muse, mutect2, varscan2
- LILRA1 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99251817; called by muse, varscan2
- MAGI2 | c.3331C>A p.P1111T | Missense Mutation (SNP) | VAF 16/491 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62686283; called by muse, mutect2
- MAL | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV59431749; called by muse, mutect2
- MAMLD1 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53373603; called by muse, mutect2
- MCTP2 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1452508536; called by muse, mutect2
- MED12L | c.2721-1G>T p.X907_splice | Splice Site (SNP) | VAF 34/892 reads (4%) | catalogued as COSV56399729; called by muse, mutect2
- MSH3 | c.2347C>A p.P783T | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778848549; called by muse, mutect2, varscan2
- MUC16 | c.40625G>A p.G13542E | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs78879019; called by mutect2, varscan2
- MYH3 | c.2377del p.C793Afs*31 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as COSV56866831; called by mutect2, pindel, varscan2
- NLRP14 | c.2597C>A p.A866D | Missense Mutation (SNP) | VAF 30/403 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55063984; called by muse, mutect2
- NR2E3 | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as rs375975199; called by mutect2, varscan2
- NRP2 | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55927407; called by muse, mutect2, varscan2
- NRXN1 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100455207; called by muse, mutect2
- NUTM2F | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV53558691; called by muse, mutect2
- OCA2 | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV62343320; called by muse, mutect2, varscan2
- OPN5 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV55245138, COSV55246687; called by muse, mutect2
- OR10A2 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV56299213; called by muse, mutect2
- OR10A5 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV55055117; called by muse, mutect2
- OR4C12 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 8/190 reads (4%) | catalogued as COSV100078546, COSV58859522, COSV58860758; called by muse, mutect2
- OR4N5 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as rs745989147; called by muse, mutect2
- OR52E4 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 21/386 reads (5%) | catalogued as COSV57623708; called by muse, mutect2
- OR52N4 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV57890350; called by muse, mutect2
- OR5T3 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV57380398; called by muse, mutect2
- PCDH17 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs769454915; called by muse, mutect2
- PCDHB11 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs1170221526, COSV61310154; called by muse, mutect2
- PGC | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63123583; called by muse, varscan2
- PHACTR3 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as COSV100732729; called by muse, mutect2
- PPP4R4 | c.1716A>T p.E572D | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV58557523; called by muse, mutect2
- PRDM16 | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54593181; called by muse, mutect2
- PTPRZ1 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV66445482; called by muse, mutect2, varscan2
- PYROXD2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100995849; called by muse, mutect2, varscan2
- REV3L | c.1378A>G p.K460E | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs762835193; called by muse, mutect2
- RTL3 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs998289867; called by muse, varscan2
- RYR3 | c.14054T>C p.V4685A (on ENST00000389232; = p.V4686A on NM_001036.6) | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66808834; called by muse, mutect2, varscan2
- SAMD9 | c.3817G>C p.E1273Q | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV101180179; called by muse, mutect2, varscan2
- SCN4A | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303471186, CM152298, COSV71128044; called by muse, mutect2
- SERPINA10 | c.641G>C p.R214P | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs145668993; called by muse, mutect2
- SERPING1 | c.904A>C p.T302P | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as CD004913, CD084222; called by muse, mutect2
- SFTPD | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV64853084; called by muse, mutect2
- SIM1 | c.1833G>T p.Q611H | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53494893; called by muse, mutect2
- SIPA1L1 | c.4423C>T p.P1475S | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.356); catalogued as COSV100665607; called by muse, mutect2
- SLC26A7 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1247624094; called by muse, mutect2
- SLC4A1 | c.2422C>A p.R808S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM951172; called by muse, mutect2, varscan2
- SPAM1 | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV56148114; called by muse, mutect2
- SPDL1 | c.1429G>T p.V477F | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs780719155; called by muse, mutect2, varscan2
- SQOR | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs866702847, COSV52943033; called by muse, mutect2, varscan2
- SRGAP3 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs758364083, COSV64537419; called by muse, mutect2
- SRPK2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs780492109; called by muse, mutect2, varscan2
- STAC | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV56218834; called by muse, varscan2
- STRAP | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs999690976; called by muse, mutect2, varscan2
- STRIP2 | c.1150A>T p.T384S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99973883; called by muse, mutect2
- STX19 | c.706A>T p.I236L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs762264967; called by muse, mutect2, varscan2
- SYT6 | c.255G>C p.W85C | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394218075; called by muse, mutect2
- TAS2R16 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.328); catalogued as COSV50796880; called by muse, mutect2, varscan2
- TDRD5 | c.1907T>A p.L636* | Nonsense Mutation (SNP) | VAF 30/678 reads (4%) | catalogued as COSV54238999; called by muse, mutect2
- TERT | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.205); catalogued as rs551522837, COSV57235436; called by muse, mutect2, varscan2
- TET1 | c.6205G>T p.E2069* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV65383015; called by muse, mutect2, varscan2
- TG | c.5695C>T p.Q1899* | Nonsense Mutation (SNP) | VAF 29/129 reads (22%) | catalogued as rs1450178339; called by muse, mutect2, varscan2
- TYR | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54471943; called by muse, mutect2
- USH2A | c.13601G>A p.G4534E | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56393689; called by muse, mutect2
- USP32 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 12/237 reads (5%) | catalogued as rs1336887677; called by muse, mutect2
- VANGL2 | c.545G>C p.R182P | Missense Mutation (SNP) | VAF 26/598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100925549; called by muse, mutect2
- VCAM1 | c.2137A>G p.I713V | Missense Mutation (SNP) | VAF 45/454 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs767369724; called by muse, mutect2, varscan2
- WDR72 | c.2801T>A p.I934K | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV64754516; called by muse, mutect2
- XIRP2 | c.9653A>G p.H3218R (on ENST00000628543; = p.H3393R on NM_152381.6) | Missense Mutation (SNP) | VAF 22/539 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1021045746; called by muse, mutect2
- XYLT1 | c.1103A>G p.H368R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs760529631; called by muse, mutect2, varscan2
- ZNF217 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56596891; called by muse, varscan2
- ZNF257 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs774629735; called by mutect2, varscan2
- ZNF366 | c.996C>A p.S332R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1433620891, COSV100574073; called by muse, mutect2
- ZNF536 | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62821271; called by muse, mutect2, varscan2
- ZNF536 | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs757667624; called by muse, mutect2, varscan2
- ABCA12 | c.4490C>G p.S1497* (on ENST00000272895 / NM_173076.3; = p.S1179* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 24/273 reads (9%) | called by muse, mutect2
- ACTA1 | c.140del p.V47Afs*21 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- ADAMTS16 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRB1 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRD1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ADH1B | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADRA1A | c.674A>T p.D225V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ANGPT1 | c.231T>A p.D77E | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2
- ANKS1B | c.1771C>A p.Q591K | Missense Mutation (SNP) | VAF 23/540 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ANO3 | c.1880C>A p.P627H | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANO6 | c.2627A>T p.K876M | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ANXA8 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AOX1 | c.2002-1G>T p.X668_splice | Splice Site (SNP) | VAF 20/351 reads (6%) | called by muse, mutect2
- APOB | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- APPBP2 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- AQP1 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP24 | c.118T>G p.W40G | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP36 | c.253+2T>A p.X85_splice | Splice Site (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.4204G>C p.G1402R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ARHGEF3 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.013); called by muse, mutect2
- ARHGEF4 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ASB2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATAD2 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP10A | c.3093T>A p.D1031E | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ATP1A1 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- ATP2B2 | c.59dup p.H20Qfs*22 | Frame Shift Ins (INS) | VAF 19/156 reads (12%) | called by mutect2, pindel, varscan2
- ATP6V0A1 | c.2164A>T p.I722F (on ENST00000343619 / NM_001378531.1; = p.I716F on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAS3 | c.1962G>T p.W654C (on ENST00000390652 / NM_001353144.2; = p.W639C on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BIVM-ERCC5 | c.2647G>T p.D883Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- BLZF1 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 14/526 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2
- BMP7 | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- C11orf53 | c.669C>A p.H223Q | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- C17orf64 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, varscan2
- C1QTNF1 | c.494T>A p.V165E | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- C4orf50 | c.716C>T p.P239L (on ENST00000324058; = p.P1471L on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2
- C6orf58 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C8A | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CADPS | c.4021A>G p.S1341G | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2
- CALCA | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2
- CALCB | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CAMK2B | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERE | c.1133A>T p.K378I | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- CCDC112 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC178 | c.161A>T p.K54M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CCL13 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.099); called by muse, mutect2
- CD163L1 | c.788G>T p.R263M | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD1A | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, varscan2
- CDC25C | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CDH17 | c.638T>A p.V213E | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDHR1 | c.1910C>A p.S637Y | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CEP41 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2
- CFAP47 | c.5329C>G p.P1777A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CH25H | c.285T>A p.H95Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CLEC14A | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CLSPN | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); called by muse, mutect2
- CLVS2 | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 69/674 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2
- CNGA3 | c.1183A>T p.I395F | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- CNN1 | c.739A>T p.M247L | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CNTNAP4 | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- COL22A1 | c.3125del p.P1042Qfs*65 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- CPA6 | c.87del p.H29Qfs*14 | Frame Shift Del (DEL) | VAF 33/147 reads (22%) | called by mutect2, pindel, varscan2
- CRACDL | c.2515G>T p.D839Y | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CREG2 | c.540del p.V181Wfs*5 | Frame Shift Del (DEL) | VAF 11/111 reads (10%) | called by mutect2, pindel, varscan2
- CRYZ | c.488T>A p.L163* | Nonsense Mutation (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- CUL3 | c.1630A>T p.S544C | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2
- CUL9 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CX3CL1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- CYP11B2 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DBT | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); called by muse, mutect2
- DCAF5 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by mutect2, varscan2
- DCBLD2 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCUN1D3 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEFB112 | c.275C>A p.S92* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2
- DEPDC1B | c.450+1G>T p.X150_splice | Splice Site (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- DGKB | c.1392dup p.P465Sfs*21 | Frame Shift Ins (INS) | VAF 36/193 reads (19%) | called by mutect2, pindel, varscan2
- DLG5 | c.2545A>C p.T849P | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.6937C>A p.P2313T (on ENST00000409039; = p.P2252T on NM_207437.3) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH3 | c.7396G>A p.G2466S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH7 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- DNAH8 | c.10524G>T p.L3508F | Missense Mutation (SNP) | VAF 22/784 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH9 | c.2783T>A p.I928N | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- DNAH9 | c.5288T>G p.M1763R | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- DOCK4 | c.4465C>A p.Q1489K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- DRAP1 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DSCAM | c.2006G>T p.C669F | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DUSP10 | c.1031A>T p.Q344L | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- ECE1 | c.280A>G p.R94G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEA1 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- EGLN3 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- ENTPD6 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPDR1 | c.335A>T p.Q112L | Missense Mutation (SNP) | VAF 17/459 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2
- EPHA8 | c.95-2A>T p.X32_splice | Splice Site (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- ERP44 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 26/244 reads (11%) | called by muse, varscan2
- ETS2 | c.1195-2A>C p.X399_splice | Splice Site (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- EVC2 | c.817-2A>T p.X273_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- EXOC2 | c.1259A>G p.H420R | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- F13A1 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by mutect2, varscan2
- FAM153A | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- FAM47A | c.1816del p.E606Kfs*42 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by pindel, varscan2
- FAM47C | c.2681C>A p.S894Y | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); called by muse, mutect2
- FANCB | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAT3 | c.1141T>A p.Y381N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.2428C>T p.Q810* | Nonsense Mutation (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- FAT3 | c.7374G>T p.K2458N | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- FAT3 | c.9437C>A p.T3146N | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); called by muse, mutect2
- FAT3 | c.13340G>T p.S4447I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- FAT4 | c.6959A>G p.Q2320R | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FBN2 | c.3631T>G p.C1211G | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FBXL7 | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.006); called by muse, mutect2
- FBXO11 | c.1045A>T p.N349Y (on ENST00000403359 / NM_001190274.2; = p.N265Y on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- FER1L6 | c.5192C>A p.A1731D | Missense Mutation (SNP) | VAF 26/594 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- FGF23 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FHL1 | c.501G>A p.K167= | Splice Region (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2, varscan2
- FLG | c.9461G>T p.G3154V | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- FLNC | c.5878G>T p.G1960C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMR1NB | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, varscan2
- FOLR1 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM1 | c.5638G>A p.G1880R | Missense Mutation (SNP) | VAF 26/717 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.253); called by muse, mutect2
- FRY | c.7853C>A p.P2618Q | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAD2 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- GALNT14 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- GCN1 | c.7240G>T p.G2414* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- GFRA1 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.118); called by muse, varscan2
- GHDC | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.575); called by muse, mutect2
- GLI2 | c.386A>T p.Y129F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLP1R | c.863A>T p.K288M | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GNA13 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.164); called by muse, mutect2
- GNL2 | c.2189A>T p.K730M | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- GPATCH2 | c.1244A>C p.H415P | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPR37 | c.1401G>C p.R467S | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- GRAP2 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.388); called by muse, mutect2
- HAND1 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.354); called by muse, mutect2
- HECW1 | c.1229T>C p.I410T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- HEPHL1 | c.344A>C p.H115P | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- HEPHL1 | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HMCN1 | c.9782G>A p.G3261E | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN1 | c.13965C>A p.C4655* | Nonsense Mutation (SNP) | VAF 17/316 reads (5%) | called by muse, mutect2
- HMCN1 | c.16061G>A p.C5354Y | Missense Mutation (SNP) | VAF 46/1566 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNF1A | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- HOXD10 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSD17B2 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- HTR3D | c.950T>A p.M317K (on ENST00000382489 / NM_001163646.2; = p.M142K on NM_182537.3) | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HYAL4 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- IFNLR1 | c.932C>A p.P311Q | Missense Mutation (SNP) | VAF 54/870 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); called by muse, mutect2
- IGLV1-50 | c.217A>T p.S73C | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2
- IGLV3-22 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- INTU | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IRAK2 | c.1856G>T p.S619I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IRF2BP2 | c.1701G>C p.M567I | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- IRF9 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 25/618 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- ISM2 | c.1129G>T p.D377Y (on ENST00000342219 / NM_199296.3; = p.R261S on NM_182509.4) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ISM2 | c.1128G>T p.K376N (on ENST00000342219 / NM_199296.3; = p.R261M on NM_182509.4) | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2
- ITGA4 | c.2104G>C p.D702H | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ITIH5 | c.2123G>A p.R708K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ITLN2 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ITPA | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITPR2 | c.4118C>G p.A1373G | Missense Mutation (SNP) | VAF 35/525 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.366); called by muse, mutect2
- JMJD1C | c.5871G>T p.Q1957H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNIP1 | c.13A>T p.M5L | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2
- KCNJ2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.158); called by muse, mutect2
- KCNK17 | c.470A>C p.Q157P | Missense Mutation (SNP) | VAF 29/678 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.425); called by muse, mutect2
- KCNU1 | c.3176T>G p.V1059G | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2
- KCTD7 | c.724A>T p.R242W (on ENST00000275532; = p.Q255L on NM_153033.5) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | PolyPhen possibly damaging (0.607); called by muse, mutect2
- KDM5A | c.2205G>T p.R735S | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- KIAA1549L | c.3019A>T p.N1007Y (on ENST00000321505; = p.N1304Y on NM_012194.3) | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIF2B | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KIF2B | c.1126G>C p.V376L | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- KLHL2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 15/297 reads (5%) | called by muse, mutect2
- KRT32 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.363); called by muse, mutect2
- LAMA1 | c.971G>T p.C324F | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA4 | c.2105T>A p.L702Q (on ENST00000230538 / NM_001105206.3; = p.L695Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- LARS1 | c.1677G>T p.R559S (on ENST00000394434 / NM_020117.11; = p.R532S on NM_016460.3) | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- LARS1 | c.1676G>T p.R559M (on ENST00000394434 / NM_020117.11; = p.R532M on NM_016460.3) | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- LCE2B | c.258C>A p.H86Q | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- LCE2D | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2
- LILRB4 | c.118A>C p.S40R | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LPA | c.3349A>T p.M1117L | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LRIT2 | c.465C>A p.Y155* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- LRP2 | c.6622G>T p.D2208Y | Missense Mutation (SNP) | VAF 18/491 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LUZP4 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- MACC1 | c.1689A>C p.Q563H | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- MAGEC1 | c.2759T>C p.L920P | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAMLD1 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MC3R | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 36/397 reads (9%) | called by muse, mutect2
- MMP10 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRGPRX4 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); called by muse, mutect2
- MRGPRX4 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2
- MSANTD4 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 48/1058 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- MUC16 | c.26446C>G p.H8816D | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MUC16 | c.16623del p.D5542Tfs*6 | Frame Shift Del (DEL) | VAF 39/374 reads (10%) | called by mutect2, varscan2
- MX2 | c.782T>A p.L261* | Nonsense Mutation (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- MYBBP1A | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MYLK | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYT1L | c.2603C>G p.P868R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); called by muse, mutect2
- MZF1 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.636); called by muse, varscan2
- N4BP1 | c.2188A>T p.N730Y | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2
- NELFB | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NELL1 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- NLRP14 | c.242del p.K81Rfs*2 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, varscan2
- NNMT | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NOL11 | c.1145_1148delinsACT p.L382Yfs*2 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2*, pindel
- NOTCH4 | c.3868G>T p.D1290Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NR3C2 | c.880A>G p.R294G | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- NRDE2 | c.3095A>T p.E1032V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NRXN3 | c.1727T>A p.L576Q (on ENST00000335750 / NM_001330195.2; = p.L203Q on NM_004796.6) | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NTM | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- NUAK1 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- NUDT2 | c.313A>T p.I105F | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- NUP98 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- OLFM3 | c.334C>G p.Q112E (on ENST00000338858 / NM_001288821.1; = p.Q92E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2
- OR10P1 | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 44/204 reads (22%) | called by mutect2, varscan2
- OR13G1 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.135); called by muse, mutect2
- OR14C36 | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2T1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- OR2T2 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- OR4K1 | c.62G>C p.W21S | Missense Mutation (SNP) | VAF 25/686 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- OR4K1 | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2
- OR56A1 | c.389G>T p.C130F | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- OR5D13 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OR5D16 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5D18 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- OR5J2 | c.467C>A p.T156K | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR6V1 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR8G1 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); called by muse, varscan2
- OSBP | c.444C>G p.N148K | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2
- PAPOLA | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2
- PAPPA2 | c.2983C>A p.H995N | Missense Mutation (SNP) | VAF 65/1396 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- PCCA | c.405G>C p.R135S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA9 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE11A | c.1234C>A p.H412N | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.229); called by muse, mutect2
- PDE3A | c.2998C>A p.L1000I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDZRN3 | c.2767G>T p.V923L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PEG10 | c.625G>T p.G209C (on ENST00000482108 / NM_001040152.2; = p.G243C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PFN4 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PHGDH | c.356+2T>C p.X119_splice | Splice Site (SNP) | VAF 8/237 reads (3%) | called by muse, mutect2
- PKD1L1 | c.6653C>T p.S2218F | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, varscan2
- PKHD1 | c.6566T>C p.V2189A | Missense Mutation (SNP) | VAF 38/975 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- PKN2 | c.2279+1G>T p.X760_splice | Splice Site (SNP) | VAF 27/506 reads (5%) | called by muse, mutect2
- PLA2G2C | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, varscan2
- PLAG1 | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- PLAT | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PLEC | c.13565A>T p.Q4522L (on ENST00000322810 / NM_201380.4; = p.Q4412L on NM_000445.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PLEKHA7 | c.3337C>T p.L1113F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.289); called by muse, mutect2
- PLEKHG2 | c.4060G>T p.A1354S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLEKHG4 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLTP | c.555C>G p.C185W | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PNLIPRP2 | c.1386G>C p.L462F (on ENST00000611850; = p.L463F on NM_005396.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2
- POLA1 | c.3788G>A p.G1263D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POM121L12 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- PPIL3 | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- PPP1R9A | c.267dup p.K90Efs*26 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- PROX1 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2
- PSD | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PSD | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRB | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PZP | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2
- RARB | c.259C>A p.P87T (on ENST00000383772 / NM_001290216.2; = p.P80T on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP3 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 19/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM27 | c.752A>T p.N251I | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- RCBTB1 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REXO5 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RFTN2 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGS7 | c.1274A>T p.H425L | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- RHAG | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 49/323 reads (15%) | called by muse, mutect2, varscan2
- RIMS1 | c.1858G>T p.V620F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIPK3 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- RNF165 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- RNF31 | c.1973G>T p.R658L | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ROBO3 | c.2983A>G p.N995D | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- RP1L1 | c.4363A>T p.S1455C | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- RPL7 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RXRG | c.774G>C p.M258I | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- RYR2 | c.2183A>T p.D728V | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SALL4 | c.1429G>C p.V477L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMD7 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB1 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2
- SBSN | c.1514C>A p.A505D (on ENST00000452271 / NM_001166034.2; = p.A162D on NM_198538.4) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SELENOI | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); called by muse, mutect2
- SEMA3A | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2
- SERPINB7 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- SIGLEC12 | c.455G>T p.R152M (on ENST00000291707 / NM_053003.4; = p.R34M on NM_033329.2) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); called by muse, mutect2
- SIPA1L3 | c.3257G>T p.G1086V | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SLC40A1 | c.1592T>A p.V531E | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A7 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- SLC4A8 | c.834T>A p.H278Q | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.266); called by muse, mutect2
- SNTG1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2
- SORCS3 | c.1537A>T p.K513* | Nonsense Mutation (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- SPOCK1 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- SRGAP3 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); called by muse, mutect2
- STOML3 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- STX3 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STXBP5 | c.2915G>T p.S972I (on ENST00000321680 / NM_001127715.2; = p.S936I on NM_139244.4) | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNPO2 | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.41); called by muse, mutect2
- SYT4 | c.1227T>A p.C409* | Nonsense Mutation (SNP) | VAF 64/598 reads (11%) | called by muse, mutect2, varscan2
- TAF15 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TARS1 | c.576G>T p.G192= | Splice Region (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- TAS2R14 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TCEAL9 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, mutect2
- TENM2 | c.1588A>T p.I530L (on ENST00000518659 / NM_001122679.2; = p.I298L on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2
- TENM2 | c.4555G>C p.D1519H (on ENST00000518659 / NM_001122679.2; = p.D1280H on NM_001080428.3) | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- TFAP2B | c.776C>G p.P259R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFB2M | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- TGFB2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THBD | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.23); called by muse, mutect2
- THBS3 | c.544-2del p.X182_splice | Splice Site (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel
- THEMIS | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TINAG | c.748+2T>A p.X250_splice | Splice Site (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- TJP1 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TLR4 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- TMEM132B | c.2313G>T p.K771N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM25 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- TMPRSS15 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- TNFRSF11A | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNIK | c.3887G>C p.G1296A | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TNR | c.2728G>T p.V910L | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TRIOBP | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRPC1 | c.1057A>G p.T353A (on ENST00000476941 / NM_001251845.2; = p.T319A on NM_003304.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.025); called by mutect2, varscan2
- TRPV6 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TSPYL6 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- TTBK1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTLL5 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TUBA3C | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2
- UGT2B10 | c.1099del p.T367Pfs*5 | Frame Shift Del (DEL) | VAF 20/178 reads (11%) | called by mutect2, varscan2
- UNC13B | c.4376G>T p.R1459L | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- USH2A | c.9044C>G p.T3015S | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- USP47 | c.1278G>C p.E426D (on ENST00000399455 / NM_001372095.1; = p.E338D on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.731); called by muse, mutect2
- VMP1 | c.975-1G>T p.X325_splice | Splice Site (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- VPS13D | c.7579G>A p.D2527N | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- VPS18 | c.92-1G>T p.X31_splice | Splice Site (SNP) | VAF 12/151 reads (8%) | called by muse, mutect2
- VWA8 | c.5271+1G>C p.X1757_splice | Splice Site (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- WARS1 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- WASF1 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- WASL | c.826+1G>T p.X276_splice | Splice Site (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- WDR45B | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- WDR7 | c.3695C>T p.A1232V | Missense Mutation (SNP) | VAF 19/472 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, mutect2
- WIPF1 | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 44/426 reads (10%) | called by muse, mutect2, varscan2
- XDH | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- XIRP2 | c.4261C>T p.Q1421* (on ENST00000628543; = p.Q1596* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- ZBBX | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 34/379 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2
- ZC3H12B | c.1720dup p.V574Gfs*7 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- ZFHX4 | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFHX4 | c.4687G>A p.V1563I | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF217 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZNF317 | c.1492G>T p.V498L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, varscan2
- ZNF329 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF385D | c.852+2T>A p.X284_splice | Splice Site (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- ZNF559 | c.1571G>T p.C524F | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF578 | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ZNF677 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF862 | c.2851G>C p.D951H | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF91 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNFX1 | c.4085C>T p.P1362L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZSWIM8 | c.3163C>T p.P1055S (on ENST00000605216 / NM_001242487.2; = p.P1060S on NM_015037.3) | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- ZW10 | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- ABCA10 | c.3012G>T p.L1004= | Silent (SNP) | VAF 26/418 reads (6%) | called by muse, mutect2
- ACSM5 | c.966C>T p.T322= | Silent (SNP) | VAF 78/1038 reads (8%) | called by muse, mutect2
- ADAMTS8 | c.2203C>T p.L735= | Silent (SNP) | VAF 39/351 reads (11%) | called by muse, mutect2, varscan2
- AHSG | c.957C>T p.T319= | Silent (SNP) | VAF 30/470 reads (6%) | called by muse, mutect2
- ARHGAP6 | c.1539C>G p.P513= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV57302799; called by muse, varscan2
- ARMCX2 | c.948G>T p.G316= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- ATP11B | c.1557A>T p.P519= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, varscan2
- ATP4A | c.1020G>T p.V340= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- BDKRB2 | c.234C>A p.V78= | Silent (SNP) | VAF 24/299 reads (8%) | catalogued as rs146975044; called by muse, mutect2
- BTBD9 | c.903A>G p.Q301= | Silent (SNP) | VAF 51/615 reads (8%) | called by muse, mutect2
- CATSPERG | c.2652A>C p.P884= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs767929449; called by mutect2, varscan2
- CDH2 | c.864C>A p.T288= | Silent (SNP) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- CDHR1 | c.1911C>A p.S637= | Silent (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- CDKL5 | c.1518C>A p.A506= | Silent (SNP) | VAF 90/330 reads (27%) | called by muse, mutect2, varscan2
- CLCA4 | c.1770T>A p.S590= | Silent (SNP) | VAF 26/287 reads (9%) | called by muse, mutect2
- CNGA2 | c.1266A>G p.T422= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- COL6A5 | c.6207T>A p.L2069= (on ENST00000312481; = p.L2065= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- CPLX2 | c.123G>A p.L41= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- CSMD1 | c.2220A>T p.I740= (on ENST00000520002; = p.I739= on NM_033225.6) | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, varscan2
- CSMD3 | c.2961A>G p.T987= (on ENST00000297405 / NM_001363185.1; = p.T883= on NM_052900.3) | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- CTNNA1 | c.633A>G p.R211= | Silent (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- CXCL6 | c.306C>A p.V102= | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- DAB2 | c.930G>T p.S310= | Silent (SNP) | VAF 30/462 reads (6%) | catalogued as rs200633845; called by muse, mutect2
- DCTPP1 | c.327C>T p.R109= | Silent (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- DENND1C | c.1608T>C p.D536= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- DIP2C | c.3477C>G p.A1159= | Silent (SNP) | VAF 9/79 reads (11%) | called by mutect2, varscan2
- DLGAP4 | c.267C>A p.P89= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- DLX4 | c.708G>T p.S236= (on ENST00000240306 / NM_138281.3; = p.S164= on NM_001934.3) | Silent (SNP) | VAF 13/56 reads (23%) | called by mutect2, varscan2
- DOCK2 | c.411C>A p.P137= | Silent (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- DSEL | c.3423G>T p.V1141= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- EHD3 | c.1032G>T p.R344= | Silent (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- EML1 | c.909A>T p.P303= | Silent (SNP) | VAF 23/259 reads (9%) | called by muse, mutect2
- FAM47A | c.315C>T p.S105= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV100650041, COSV60493876; called by muse, mutect2
- FAM83B | c.1422C>A p.I474= | Silent (SNP) | VAF 28/326 reads (9%) | catalogued as rs1241351724, COSV60920800; called by muse, mutect2
- FAT3 | c.1524C>G p.T508= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- FBXL7 | c.1267C>T p.L423= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- FCRL3 | c.1455C>T p.A485= | Silent (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- FCRL6 | c.1173G>T p.G391= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as rs201486126; called by muse, mutect2, varscan2
- FGD5 | c.1914C>A p.I638= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV53246819; called by muse, mutect2
- FIBIN | c.610C>T p.L204= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV100590542; called by muse, mutect2, varscan2
- FLG2 | c.4917A>C p.T1639= | Silent (SNP) | VAF 44/646 reads (7%) | catalogued as COSV66169244; called by muse, mutect2
- FPR2 | c.513T>C p.N171= | Silent (SNP) | VAF 58/263 reads (22%) | catalogued as rs756709671; called by muse, mutect2, varscan2
- FSCB | c.531A>G p.S177= | Silent (SNP) | VAF 50/440 reads (11%) | called by muse, mutect2, varscan2
- G6PC2 | c.996C>A p.P332= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- GALNT17 | c.525C>A p.A175= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as COSV61174178, COSV61174933; called by muse, mutect2, varscan2
- GBX1 | c.534G>T p.L178= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- GJD2 | c.456G>A p.G152= | Silent (SNP) | VAF 13/424 reads (3%) | called by muse, mutect2
- GLT8D2 | c.732C>A p.T244= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- GPR85 | c.543T>A p.A181= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- HHIPL1 | c.375G>T p.L125= | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- HS3ST4 | c.678G>A p.V226= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- HTR3C | c.579C>A p.G193= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.396C>G p.T132= | Silent (SNP) | VAF 29/266 reads (11%) | catalogued as rs1567821494; called by muse, mutect2, varscan2
- IGKV3D-11 | c.204C>T p.I68= | Silent (SNP) | VAF 34/170 reads (20%) | called by muse, varscan2
- IL27 | c.381C>T p.G127= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- INPP5J | c.2178C>T p.A726= (on ENST00000331075 / NM_001284285.2; = p.A358= on NM_001002837.2) | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as rs1336317551; called by muse, mutect2
- IRX2 | c.1179A>T p.T393= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- ITFG2 | c.900A>T p.S300= | Silent (SNP) | VAF 69/484 reads (14%) | catalogued as COSV57389867; called by muse, mutect2, varscan2
- ITGA8 | c.2514C>T p.T838= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as COSV65228217; called by muse, varscan2
- KCNJ8 | c.27G>A p.P9= | Silent (SNP) | VAF 17/277 reads (6%) | called by muse, mutect2
- KIF2B | c.444C>A p.P148= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as rs752661021, COSV99275568; called by mutect2, varscan2
- KLHL25 | c.99G>A p.L33= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- KMT2A | c.10221A>G p.P3407= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- LAMA1 | c.519C>A p.T173= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs1483075851, COSV101056688; called by muse, mutect2
- LAMA4 | c.2104C>T p.L702= (on ENST00000230538 / NM_001105206.3; = p.L695= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- LAMC2 | c.162C>G p.L54= | Silent (SNP) | VAF 152/1185 reads (13%) | catalogued as COSV51452946, COSV51454530; called by muse, mutect2, varscan2
- LAMP5 | c.657C>T p.F219= | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- LHFPL1 | c.213C>A p.A71= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as COSV64333700; called by muse, mutect2, varscan2
- LHFPL5 | c.171G>A p.P57= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as rs898563542, COSV64177058, COSV64178691; called by muse, mutect2, varscan2
- LILRA6 | c.540G>T p.L180= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1255961115; called by muse, mutect2, varscan2
- METTL2B | c.882C>A p.G294= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99300045; called by muse, mutect2, varscan2
- MS4A14 | c.36C>T p.H12= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs200092161; called by muse, mutect2, varscan2
- MYBPC2 | c.639G>A p.E213= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- MYO10 | c.4425C>T p.Y1475= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- N4BP1 | c.2187G>T p.V729= | Silent (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- NLRP5 | c.2355G>A p.Q785= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- NLRP5 | c.3072C>T p.G1024= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs750778706; called by muse, mutect2, varscan2
- NLRP7 | c.762C>A p.G254= | Silent (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- NOTCH4 | c.3867G>T p.G1289= | Silent (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- NPAS4 | c.1023C>T p.T341= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as rs773159818, COSV100215235; called by muse, mutect2, varscan2
- OAS3 | c.2574C>G p.V858= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99966013; called by muse, mutect2
- OR10A6 | c.372T>A p.A124= | Silent (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- OR2L2 | c.654C>A p.G218= | Silent (SNP) | VAF 45/440 reads (10%) | called by muse, varscan2
- OR2T2 | c.42C>A p.V14= | Silent (SNP) | VAF 32/414 reads (8%) | catalogued as COSV61619363; called by muse, mutect2
- OR4C13 | c.711C>G p.T237= | Silent (SNP) | VAF 21/394 reads (5%) | called by muse, mutect2
- OR4D10 | c.660C>A p.V220= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV73259974; called by muse, mutect2
- OR51G1 | c.861C>A p.P287= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- OR51G2 | c.756T>C p.A252= | Silent (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- OR56A3 | c.660C>G p.L220= | Silent (SNP) | VAF 49/508 reads (10%) | called by muse, mutect2
- OR5B17 | c.142C>T p.L48= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV62160506; called by muse, mutect2
- OR9A2 | c.681C>T p.A227= | Silent (SNP) | VAF 32/207 reads (15%) | called by muse, mutect2, varscan2
- P2RX1 | c.834G>C p.G278= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs12602000; called by muse, mutect2, varscan2
- PCDHA13 | c.1182C>T p.P394= | Silent (SNP) | VAF 37/275 reads (13%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.1590C>T p.S530= | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- PCDHGA4 | c.1857G>T p.V619= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- PEG3 | c.549C>A p.T183= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PKDREJ | c.1752T>C p.C584= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- PKHD1 | c.8355G>C p.V2785= | Silent (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- PLB1 | c.3009A>G p.P1003= | Silent (SNP) | VAF 133/700 reads (19%) | called by muse, varscan2
- PLXNA4 | c.4428C>A p.A1476= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- PPFIA4 | c.2616G>T p.R872= (on ENST00000447715; = p.R873= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- PRPF3 | c.1314A>G p.V438= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1553871980; called by muse, mutect2
- PRR5L | c.198G>C p.G66= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- PTPRZ1 | c.2181T>A p.A727= | Silent (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- RAG1 | c.2214G>C p.L738= | Silent (SNP) | VAF 17/220 reads (8%) | called by muse, mutect2
- RARA | c.429C>T p.C143= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- RFX3 | c.1932G>A p.Q644= | Silent (SNP) | VAF 11/274 reads (4%) | called by muse, mutect2
- RP1L1 | c.1972C>A p.R658= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV66757381; called by muse, mutect2, varscan2
- RTL9 | c.303C>A p.S101= | Silent (SNP) | VAF 48/531 reads (9%) | catalogued as COSV71826387; called by muse, mutect2
- SLC35B4 | c.807C>G p.V269= | Silent (SNP) | VAF 64/716 reads (9%) | called by muse, mutect2
- SLC41A1 | c.327A>C p.A109= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- SLC5A7 | c.396T>A p.I132= | Silent (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- SLC6A6 | c.546C>A p.V182= | Silent (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- SRSF6 | c.912G>C p.P304= | Silent (SNP) | VAF 12/153 reads (8%) | catalogued as COSV54828215; called by muse, mutect2
- STYXL2 | c.1701C>T p.S567= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as rs372727539; called by muse, mutect2, varscan2
- SYNE1 | c.15939T>G p.T5313= (on ENST00000367255 / NM_182961.4; = p.T5242= on NM_033071.3) | Silent (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- TAF2 | c.2406G>T p.L802= | Silent (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- TMEM108 | c.1443C>T p.S481= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV58882038; called by muse, mutect2, varscan2
- TMEM181 | c.771C>T p.L257= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs1026378069; called by muse, mutect2, varscan2
- TNC | c.5505C>A p.G1835= | Silent (SNP) | VAF 56/309 reads (18%) | catalogued as COSV60785106; called by muse, mutect2, varscan2
- TRIM51 | c.699G>T p.L233= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- TSPYL5 | c.477G>A p.G159= | Silent (SNP) | VAF 32/358 reads (9%) | called by muse, mutect2
- TTN | c.87165A>T p.A29055= (on ENST00000591111; = p.A21631= on NM_003319.4) | Silent (SNP) | VAF 30/187 reads (16%) | called by muse, mutect2, varscan2
- UGT3A1 | c.528G>T p.G176= | Silent (SNP) | VAF 58/263 reads (22%) | catalogued as rs746813440; called by muse, mutect2, varscan2
- USH2A | c.4680A>C p.A1560= | Silent (SNP) | VAF 8/181 reads (4%) | catalogued as rs1233583863; ClinVar: likely benign; called by muse, mutect2
- USP19 | c.951G>A p.E317= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- USP20 | c.2229C>T p.P743= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- XIRP2 | c.8844T>C p.F2948= (on ENST00000628543; = p.F3123= on NM_152381.6) | Silent (SNP) | VAF 30/393 reads (8%) | called by muse, mutect2
- XK | c.1212C>T p.P404= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- YTHDF1 | c.1326G>T p.G442= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1419542415, COSV100945594; called by muse, mutect2, varscan2
- YY1AP1 | c.2217A>C p.S739= (on ENST00000295566 / NM_139118.2; = p.S682= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- ZNF142 | c.3648G>A p.L1216= (on ENST00000411696 / NM_001379660.1; = p.L1016= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as rs180956508; called by muse, mutect2, varscan2
- ZNF333 | c.1866G>A p.Q622= | Silent (SNP) | VAF 46/496 reads (9%) | called by muse, mutect2
- ZNF99 | c.981C>A p.A327= | Silent (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- ZPLD1 | c.420A>G p.P140= (on ENST00000466937 / NM_001329788.1; = p.P156= on NM_175056.2) | Silent (SNP) | VAF 52/614 reads (8%) | called by muse, mutect2
- AP000769.5 | chr11:65500608 A>G | 5'Flank (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2
- C16orf82 | c.-153C>A | 5'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- C5orf64 | n.512+51984A>T | Intron (SNP) | VAF 30/267 reads (11%) | catalogued as rs781586320; called by muse, mutect2, varscan2
- EIF4G1 | c.3121+86G>T | Intron (SNP) | VAF 37/182 reads (20%) | catalogued as COSV59993608; called by muse, mutect2, varscan2
- FAM74A3 | n.187C>A | RNA (SNP) | VAF 6/58 reads (10%) | catalogued as rs1256420217; called by mutect2, varscan2
- FMO3 | c.133-2019C>T | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as COSV63008667; called by muse, mutect2, varscan2
- HOXB3 | c.-2C>A | 5'UTR (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- IGSF1 | c.-105T>A | 5'UTR (SNP) | VAF 12/127 reads (9%) | catalogued as rs751841097; called by muse, mutect2, varscan2
- PPP2R3A | c.1996-3638A>T | Intron (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- SNORD64 | n.8T>G | RNA (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- SYNJ2 | c.3744+800G>T | Intron (SNP) | VAF 40/183 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10361-4466C>T | Intron (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10361-5271C>G | Intron (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- UBTFL2 | n.379G>T | RNA (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1945G>A | Intron (SNP) | VAF 23/363 reads (6%) | called by muse, mutect2
